Somatic mutation profile of tumor specimen PCProject_0575_T1_WES (aliquot PCProject_0575_T1_WES_1) from CMI case PCProject_0575, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.7 years (26,199 days).
Specimen PCProject_0575_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f28d461c-fb99-443f-b0fb-17f71ba56527.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0575_SALIVA (DNA), aliquot PCProject_0575_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c832999-8c7d-47a4-937f-09e19e533e4d

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 4, 3'UTR 2, Frame Shift Del 1, Nonsense Mutation 1, Intron 1, IGR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1D | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs1454670834; called by muse, mutect2, varscan2
- ATRX | c.477dup p.R160Tfs*29 | Frame Shift Ins (INS) | VAF 86/272 reads (32%) | catalogued as COSV64870011; called by mutect2, pindel, varscan2
- DDX51 | c.1685C>T p.T562M | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375884335; called by muse, mutect2, varscan2
- FAM189A1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); catalogued as rs770813094, COSV54270219; called by muse, mutect2, varscan2
- FCHO1 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 68/347 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs755561445; called by muse, mutect2, varscan2
- KMT2D | c.9308C>T p.A3103V | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs755031010, COSV56443140; called by muse, mutect2, varscan2
- KRT2 | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 259/1061 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV100548565; called by muse, mutect2, varscan2
- NOL11 | c.542T>A p.V181E | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1209745874; called by muse, mutect2, varscan2
- NTN5 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs752844872; called by muse, mutect2, varscan2
- PPP3CA | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 32/757 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59921756; called by muse, mutect2
- PTGES3L-AARSD1 | c.364G>A p.E122K (on ENST00000421990 / NM_001136042.2; = p.E104K on NM_025267.3) | Missense Mutation (SNP) | VAF 79/467 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1286566552; called by muse, mutect2, varscan2
- SLC34A1 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs17854804; called by muse, mutect2, varscan2
- VEZT | c.1985A>C p.E662A | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54137023; called by muse, mutect2, varscan2
- ZAN | c.2624C>T p.T875M | Missense Mutation (SNP) | VAF 79/405 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs370504357; called by muse, mutect2, varscan2
- ABCA12 | c.7511T>C p.M2504T (on ENST00000272895 / NM_173076.3; = p.M2186T on NM_015657.3) | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- ANKRD37 | c.441_472del p.S148Lfs*7 | Frame Shift Del (DEL) | VAF 80/362 reads (22%) | called by mutect2, pindel
- FBLN2 | c.1004G>T p.R335M | Missense Mutation (SNP) | VAF 203/943 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FKBP15 | c.2128A>G p.S710G | Missense Mutation (SNP) | VAF 25/494 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.079); called by muse, mutect2
- GAS2L2 | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GIPR | c.1221G>C p.W407C | Missense Mutation (SNP) | VAF 140/685 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- LRRC9 | c.2315T>G p.L772R | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRK1 | c.4611G>T p.Q1537H | Missense Mutation (SNP) | VAF 111/532 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NELL1 | c.1332C>A p.Y444* | Nonsense Mutation (SNP) | VAF 65/298 reads (22%) | called by muse, mutect2, varscan2
- OCEL1 | c.660G>C p.E220D | Missense Mutation (SNP) | VAF 23/434 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2
- SLC25A11 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- STYX | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.065); called by muse, mutect2
- UBA5 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- XRCC3 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 165/878 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM6A | c.2490A>C p.P830= | Silent (SNP) | VAF 123/236 reads (52%) | catalogued as rs765392570, COSV65037069; called by muse, mutect2, varscan2
- MANBA | c.2496C>T p.N832= (on ENST00000642252; = p.N786= on NM_005908.4) | Silent (SNP) | VAF 203/943 reads (22%) | catalogued as rs767182713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PZP | c.3801G>A p.L1267= | Silent (SNP) | VAF 82/394 reads (21%) | catalogued as rs1261181205; called by muse, mutect2, varscan2
- SYNJ2 | c.3252C>T p.V1084= | Silent (SNP) | VAF 105/395 reads (27%) | catalogued as rs1335229384; called by muse, mutect2, varscan2
- KDELR2 | c.*141del | 3'UTR (DEL) | VAF 79/333 reads (24%) | called by mutect2, pindel, varscan2
- KLC1 | c.*6033G>C | 3'UTR (SNP) | VAF 140/676 reads (21%) | called by muse, mutect2, varscan2
- NMRAL1 | c.720+12G>A | Intron (SNP) | VAF 152/621 reads (24%) | catalogued as rs1244394584; called by muse, mutect2, varscan2
- Unknown | chr17:43377698 A>G | IGR (SNP) | VAF 183/872 reads (21%) | called by muse, mutect2, varscan2
